Gene-level copy-number profile of tumor specimen ALCH-ABEF-TTP1-A from ALCHEMIST case ALCH-ABEF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.5 years (23,940 days).
Specimen ALCH-ABEF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6955273c-7f71-469a-8667-f4b05f2f3bf5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABEF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/dc602b68-57a8-4366-9cc5-a378f3205791

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 31; copy number 3: 3,100; copy number 4: 36,391; copy number 5: 2,423; copy number 6: 13,802; copy number 7: 2,525; copy number 8: 27; copy number 9: 14; copy number 10: 1; copy number 11: 6; copy number 13: 73.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 94 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,899,077–181,007,384, 8 genes, copy number 9: BTNL8, Y_RNA, RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P.
- chr7:38,269,491–38,300,322, 6 genes, copy number 11 (within-gene range 4–11): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr11:63,369,785–63,410,294, 1 gene, copy number 10: SLC22A9.
- chr14:22,052,514–22,513,998, 72 genes, copy number 13 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 13: TRAC.
- chr14:100,894,817–100,927,413, 6 genes, copy number 9: AL117190.6, SNORD112, AL117190.4, MIR370, SNORD113-1, SNORD113-2.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
